Somatic mutation profile of tumor specimen TARGET-10-PAPHNR-09A (aliquot TARGET-10-PAPHNR-09A-01D) from TARGET case TARGET-10-PAPHNR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.1 years (3,325 days).
Specimen TARGET-10-PAPHNR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6643ca5c-a9e7-4abf-83df-805dd15dffb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPHNR-10A (Blood Derived Normal), aliquot TARGET-10-PAPHNR-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d48c49e-1f42-42cc-8dbe-79483906926e

The open-access MAF lists 13 somatic variants for this specimen: 11 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Frame Shift Ins 2, In Frame Ins 1, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRV1 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397517439; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BAMBI | c.653C>T p.P218L | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs573231648; called by muse, mutect2, varscan2
- FOXI3 | c.1174G>A p.G392R | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as rs1230707744; called by muse, mutect2, varscan2
- GRIA4 | c.2404A>G p.S802G | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV56895365; called by muse, mutect2, varscan2
- MYH14 | c.4474G>A p.E1492K | Missense Mutation (SNP) | VAF 9/103 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs1394306209; called by muse, mutect2
- CCDC148 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- DOCK1 | c.5347_5348insGGGG p.S1783Wfs*119 | Frame Shift Ins (INS) | VAF 42/165 reads (25%) | called by mutect2, pindel, varscan2
- GMFB | c.349_350insACGGTCC p.L117Hfs*8 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- PIGO | c.615_616insGCA p.D205_T206insA | In Frame Ins (INS) | VAF 20/47 reads (43%) | called by mutect2, pindel, varscan2
- PTPRE | c.995T>C p.V332A | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- CORO1B | c.*936T>G | 3'UTR (SNP) | VAF 17/33 reads (52%) | called by muse, mutect2, varscan2
- UBTFL2 | n.335G>A | RNA (SNP) | VAF 54/150 reads (36%) | catalogued as rs367959095; called by muse, mutect2, varscan2
